Surgical pathology report (de-identified scan), TCGA case TCGA-X3-A8G4, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Cleveland Clinic Foundation, specimen TCGA-X3-A8G4-01A (Primary Tumor).

[page 1 of 3]
Encounter Date:

Results

SURGICAL PATHOLOGY (Order

Patient Info

Patient Name

Sex

DOB

Results

Specimen #:
Submitting Physician:

FINAL DIAGNOSIS

Left testis, orchiectomy - Mixed germ cell tumor, composed of seminoma (40%), yolk sac (35%), embryonal carcinoma (20%) and teratoma (5%).

- The tumor is confined to the testis.
- Intratubular germ cell neoplasia.
- Lymphovascular space invasion is not identified.
- Rete testis, epididymis, and spermatic cord, negative.
- All surgical margins including spermatic cord margin are negative for malignancy.

> These %s in
Open Clinica.

BCR

COMMENT

Radical Orchiectomy

Specimen Laterality: Left

Tumor Focality: Unifocal

Tumor Size: 5.8 x 5.2 x 3.5 cm.

Macroscopic Extent of Tumor: (select all that apply)
Confined to the testis

Histologic Type: Mixed germ cell tumor (seminoma (45%), yolk sac (35%), embryonal carcinoma (20%), teratoma (5%)

Margins:

Spermatic Cord Margin: Uninvolved by tumor
Other Margin(s): Uninvolved by tumor

Microscopic Tumor Extension: (select all that apply)
None of the above

Lymph-Vascular Invasion: Absent

Serum Tumor Markers: (S)
AFP elevation
beta-HCG elevation

Additional Pathologic Findings: Intratubular germ cell neoplasia

Pathologic Staging (pTNM)

ICD-O-3
Mixed germ cell tumor 9085/3
Site @ Testis NOS C62.9
Jr 4/4/14

[page 2 of 3]
Encounter Date:

Primary Tumor: (pT) pT1: Tumor limited to the testis and epididymis without vascular/lymphatic invasion; tumor may invade tunica albuginea but not tunica vaginalis

Regional Lymph Nodes: (pN) pNX: Cannot be assessed

Distant Metastasis: (pM) pMX

(Electronic Signature)

SPECIMEN SUBMITTED
A: LEFT TESTIS

CLINICAL DATA
TESTI CA

GROSS DESCRIPTION

A. Received in formalin at the surgical desk is a specimen labeled "left testis". It consists of a testicle attached to a segment of spermatic cord. The testis weighs 121.4 grams, and measures 8 x 5.5 x 3.7 cm. The spermatic cord measures 10 cm in length. After bivalving the testis, a 5.8 x 5.2 x 3.5 cm mass is identified. It is observed to replace approximately 90% of the testicular parenchyma. There is a rim of normal appearing tan colored parenchyma on the inferior pole of the testis. The mass is solitary and heterogeneous, showing tan colored mucinous areas with small cysts that measure up to 0.5 cm, necrosis, white-tan rubbery areas and hemorrhagic areas. The tumor does not involve the tunica albuginea or vaginalis. The epididymis is not grossly involved by neoplasm. Neoplasm does not involve the spermatic cord. Sections are submitted as follows: A1 distal spermatic cord (shave margin), A2 mid spermatic cord, A3 proximal spermatic cord, A4 mass in relation to tunica vaginalis, A5 mass in relation to tunica albuginea, A6 mass in relation to normal parenchyma, A7-A9 additional representative sections of mass, A10 representative sections of mucinous area with small cyst, A11 representative section of hemorrhagic areas, A12 representative sections epididymis in relation to mass.

Patient ID #: [REDACTED]

Date of Report:

Date of Procedure:

Date of Receipt:

Submitted by:

Location:

Test performed by:

Lab and Collection

SURGICAL PATHOLOGY (Order)

on

- Lab and Collection Information

Result History

SURGICAL PATHOLOGY (Order)

on

- Order Result History Report

Result Information

Result Date and Time

Status
Final result

Provider Status
Reviewed

[page 3 of 3]
Encounter Date: ..

This result is currently not released to
Display Full Result Report

Display Order Report

ICD9A1 Discrepancy		///
Metastatic/Synchronous Primary Malignancy		///
Case is (include):		
Reviewed Initial	CONFIRMED	DISQUALIFIED

Source: NCI Genomic Data Commons file 456a0936-4725-4e00-b3d9-d114e6fd3770 (TCGA-X3-A8G4.2A93BBE1-5291-4B00-BA41-14D2C47ED6F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).